Somatic mutation profile of tumor specimen TCGA-S9-A6UA-01A (aliquot TCGA-S9-A6UA-01A-12D-A33T-08) from TCGA case TCGA-S9-A6UA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.4 years (24,242 days).
Specimen TCGA-S9-A6UA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4011f4b-4da0-46bc-9e0c-1e69da878c73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6UA-10A (Blood Derived Normal), aliquot TCGA-S9-A6UA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d977c284-130c-4d6c-9061-b0b6a263848b

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 10, Frame Shift Del 3, Splice Site 2, Intron 1, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1020dup p.V341Cfs*12 | Frame Shift Ins (INS) | VAF 57/223 reads (26%) | catalogued as rs1555610905, CI086448; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHDC1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs753110793, COSV99899839; called by muse, mutect2, varscan2
- ATRX | c.3810-1G>A p.X1270_splice | Splice Site (SNP) | VAF 33/69 reads (48%) | catalogued as COSV100971624; called by muse, mutect2, varscan2
- B3GNTL1 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302288; called by muse, varscan2
- C1RL | c.36G>C p.W12C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV99865028; called by muse, mutect2, varscan2
- CDH23 | c.7886G>A p.R2629H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as rs763331998, COSV56495028; called by muse, mutect2, varscan2
- CHD9 | c.3404A>G p.N1135S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1255885860, COSV54613982; called by muse, mutect2, varscan2
- GNPTAB | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 37/835 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775948211, COSV54777029; called by muse, mutect2
- HPS4 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100404784; called by muse, mutect2, varscan2
- KERA | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs145871038; called by muse, mutect2, varscan2
- LRRC7 | c.1852G>C p.V618L (on ENST00000651989 / NM_001370785.2; = p.V585L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV99230494; called by muse, mutect2, varscan2
- MKI67 | c.7151G>A p.G2384D | Missense Mutation (SNP) | VAF 52/802 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); catalogued as rs577377467, COSV100896391, COSV100897088; called by muse, mutect2
- NF1 | c.7783A>T p.K2595* (on ENST00000358273 / NM_001042492.3; = p.K2574* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 98/474 reads (21%) | catalogued as CM143480, COSV100648501, COSV62197108; called by muse, mutect2, varscan2
- NME8 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99553987; called by muse, mutect2, varscan2
- PER1 | c.2474G>T p.G825V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as COSV100424941; called by muse, mutect2, varscan2
- PRKCG | c.1373+1G>A p.X458_splice | Splice Site (SNP) | VAF 21/88 reads (24%) | catalogued as COSV54731417; called by muse, mutect2, varscan2
- PSMB1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.963); catalogued as COSV51530253; called by muse, mutect2, varscan2
- PTPN1 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99247376; called by muse, mutect2, varscan2
- PYM1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100212721; called by muse, mutect2
- RABEP1 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV99337075; called by muse, mutect2, varscan2
- SCYL3 | c.1270A>C p.T424P | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV100884332; called by muse, mutect2, varscan2
- SIAH1 | c.564C>G p.H188Q | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV99589617; called by muse, mutect2
- SLC30A3 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99273981; called by muse, mutect2, varscan2
- SLC30A5 | c.1070T>C p.L357S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV101173668; called by muse, mutect2, varscan2
- SPATS2L | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV100660904; called by muse, mutect2
- TDRD9 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 40/545 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100175810; called by muse, mutect2
- TOM1L1 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 142/353 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100779561; called by muse, mutect2, varscan2
- WASF2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780474007, COSV101420831; called by muse, mutect2, varscan2
- XXYLT1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100118610, COSV100118835; called by muse, mutect2, varscan2
- ERAP2 | c.1385del p.L462* | Frame Shift Del (DEL) | VAF 47/241 reads (20%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.549_550del p.R183Sfs*6 | Frame Shift Del (DEL) | VAF 36/218 reads (17%) | called by pindel, varscan2
- PPM1D | c.1447_1448del p.T483Ffs*5 | Frame Shift Del (DEL) | VAF 64/294 reads (22%) | called by mutect2, pindel, varscan2
- CHST15 | c.30G>A p.Q10= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- CLCN4 | c.1137C>T p.I379= | Silent (SNP) | VAF 26/292 reads (9%) | catalogued as COSV101074114; called by muse, mutect2
- CLDN6 | c.397C>T p.L133= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100172426; called by muse, mutect2, varscan2
- COL15A1 | c.1110C>T p.S370= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as COSV100898076; called by muse, mutect2, varscan2
- ESPN | c.1050G>A p.P350= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs559886623, COSV100911425; called by muse, mutect2, varscan2
- IGHV1-46 | c.42T>G p.A14= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- RCBTB2 | c.1137A>G p.T379= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100749670; called by muse, mutect2, varscan2
- SEC61A1 | c.756T>C p.F252= | Silent (SNP) | VAF 95/347 reads (27%) | catalogued as COSV99685089; called by muse, mutect2, varscan2
- ZNF143 | c.1440C>T p.D480= | Silent (SNP) | VAF 41/307 reads (13%) | catalogued as rs763052310, COSV100217710; called by muse, mutect2, varscan2
- ZNF646 | c.2505C>T p.G835= | Silent (SNP) | VAF 57/230 reads (25%) | catalogued as COSV99762734; called by muse, mutect2, varscan2
- MACF1 | c.15832-9939C>T | Intron (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99247455; called by muse, mutect2, varscan2
- MESD | c.*2G>A | 3'UTR (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99930921; called by muse, mutect2, varscan2
